Somatic mutation profile of tumor specimen 0DPUTK from CCDI case PBCDMK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 1.7 years (639 days).
Specimen 0DPUTK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 466224f2-9156-4e01-af7b-13bc95a966c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPUTG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b33f2a9-2ee4-4be8-96e2-9648b57d5721

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Splice Site 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RECQL5 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 166/376 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs201204572, COSV58638162; called by muse, mutect2, varscan2
- NEB | c.6915+1G>A p.X2305_splice | Splice Site (SNP) | VAF 341/684 reads (50%) | called by muse, mutect2, varscan2
- RPL11 | c.393+53_393+54del | Intron (DEL) | VAF 58/181 reads (32%) | catalogued as rs1302365671; called by mutect2, varscan2
